Somatic mutation profile of tumor specimen d4377e17-ca1c-4411-a386-8d5f4c (aliquot d4377e17-ca1c-4411-a386-8d5f4c_D6) from CPTAC case 17OV028, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC.
Specimen d4377e17-ca1c-4411-a386-8d5f4c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79f4eae3-4a6d-424e-b10d-b09b0a3ec149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 80a5ccde-c851-47fb-8c0d-238b16 (Blood Derived Normal), aliquot 80a5ccde-c851-47fb-8c0d-238b16_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7543a2a3-74c9-4dae-b8bc-dca72b742866

The open-access MAF lists 222 somatic variants for this specimen: 156 protein-altering or splice-affecting, 40 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 40, Intron 18, Nonsense Mutation 9, Splice Region 5, Splice Site 5, Frame Shift Del 3, In Frame Del 3, 5'UTR 3, RNA 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3427C>A p.Q1143K | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as CM073958; called by mutect2, varscan2
- ADAMTS17 | c.3011C>T p.T1004I | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs1292094234; called by muse, mutect2, varscan2
- ANKRD30B | c.2224G>A p.V742M | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1272112314; called by muse, varscan2
- ANO5 | c.701G>T p.R234M | Missense Mutation (SNP) | VAF 52/359 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs749374398, COSV100201748, COSV61086066; called by mutect2, varscan2
- APBB2 | c.1129C>A p.P377T (on ENST00000295974 / NM_001166050.2; = p.P378T on NM_004307.2) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as COSV55953739; called by muse, mutect2, varscan2
- C3orf56 | c.364G>T p.A122S | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV67756283; called by mutect2, varscan2
- C5 | c.1762G>C p.V588L | Missense Mutation (SNP) | VAF 132/315 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.047); catalogued as rs1295308735, COSV56327339; called by muse, mutect2, varscan2
- CAVIN2 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 248/1027 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58424350, COSV58425725; called by muse, mutect2, varscan2
- CCN4 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 42/357 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1252087413; called by muse, mutect2, varscan2
- CDHR1 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV60567123; called by muse, mutect2, varscan2
- CENPF | c.4636G>A p.A1546T | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as rs768578259; called by muse, mutect2, varscan2
- CLCA1 | c.450A>G p.Q150= | Splice Region (SNP) | VAF 8/70 reads (11%) | catalogued as rs1025408344; called by muse, varscan2
- COLEC10 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 38/578 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV60520713; called by muse, mutect2
- COLGALT2 | c.609G>C p.W203C | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62730193; called by muse, mutect2, varscan2
- CRISPLD1 | c.999A>G p.Q333= | Splice Region (SNP) | VAF 14/86 reads (16%) | catalogued as rs779620373; called by muse, mutect2, varscan2
- DNAJA1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as rs1288869570; called by muse, mutect2, varscan2
- DTWD2 | c.389G>C p.R130P | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771577328, COSV100406947; called by muse, mutect2, varscan2
- DUOX2 | c.4613G>A p.R1538Q | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758697659, COSV101199706; called by muse, mutect2, varscan2
- EN2 | c.941T>C p.M314T | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs985798739; called by muse, mutect2, varscan2
- ERFE | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.67); catalogued as rs1021973835; called by mutect2, varscan2
- FAM161A | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1433311081; called by muse, mutect2, varscan2
- GADL1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs145224145, COSV56981876, COSV56983905; called by muse, mutect2, varscan2
- GALNT17 | c.508C>G p.R170G | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100351938; called by muse, mutect2, varscan2
- GTF2F2 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs776881435; called by muse, mutect2, varscan2
- IGDCC3 | c.1588C>T p.R530* | Nonsense Mutation (SNP) | VAF 72/103 reads (70%) | catalogued as rs143782720, COSV60077810; called by muse, mutect2, varscan2
- IMPG1 | c.1201G>C p.V401L | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs769673335; called by muse, mutect2
- KALRN | c.5239G>T p.A1747S (on ENST00000360013 / NM_001024660.4; = p.A50S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/297 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs761274205; called by muse, mutect2, varscan2
- KBTBD7 | c.1976C>G p.S659* | Nonsense Mutation (SNP) | VAF 60/169 reads (36%) | catalogued as COSV101068150; called by muse, mutect2, varscan2
- LRRTM1 | c.684C>A p.H228Q | Missense Mutation (SNP) | VAF 126/372 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs767640018; called by muse, mutect2, varscan2
- MOV10L1 | c.743+1G>A p.X248_splice | Splice Site (SNP) | VAF 6/33 reads (18%) | catalogued as rs779231200; called by muse, mutect2, varscan2
- MUC5B | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 28/387 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770580785, COSV71590494; called by muse, mutect2
- MYO9B | c.4934C>T p.S1645L | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as rs762171057; called by muse, mutect2, varscan2
- NIPBL | c.928G>C p.V310L | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.012); catalogued as COSV56966473; called by muse, mutect2
- NME8 | c.1282G>T p.V428F | Missense Mutation (SNP) | VAF 76/240 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV99552927; called by muse, mutect2, varscan2
- NOD1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 197/479 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1371565397, COSV56115028; called by muse, mutect2, varscan2
- NTNG2 | c.405C>G p.D135E | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV62364085, COSV62366514; called by mutect2, varscan2
- OR4K2 | c.22A>G p.T8A | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53852035; called by muse, mutect2, varscan2
- OR52L1 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV59986292; called by muse, mutect2, varscan2
- P4HA2 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 60/131 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.226); catalogued as rs771208496, CM152961; called by muse, mutect2, varscan2
- PCDHGB6 | c.1591A>G p.T531A | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.963); catalogued as COSV53994234; called by muse, mutect2, varscan2
- PCSK6 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1171000557; called by muse, mutect2, varscan2
- PNLIP | c.14G>T p.W5L | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.325); catalogued as COSV65041884; called by mutect2, varscan2
- PPP2R1A | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100436093; called by muse, mutect2
- PRB3 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 131/250 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.06); catalogued as rs376441621, COSV54391702; called by muse, mutect2, varscan2
- SKIV2L | c.1405C>A p.R469= | Splice Region (SNP) | VAF 11/52 reads (21%) | catalogued as COSV64811447; called by muse, mutect2, varscan2
- SPART | c.1045C>G p.Q349E | Missense Mutation (SNP) | VAF 70/397 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV62088783; called by muse, mutect2, varscan2
- SPTA1 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 52/465 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs372937123, COSV63757170; called by muse, mutect2, varscan2
- SPZ1 | c.47C>G p.T16S | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as COSV57062630, COSV99698273; called by muse, mutect2, varscan2
- TCF23 | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV56078525; called by mutect2, varscan2
- UBE2QL1 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs982730698; called by muse, mutect2, varscan2
- USH2A | c.14115C>A p.F4705L | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.334); catalogued as COSV56351050; called by muse, mutect2, varscan2
- WNK3 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs1311012318; called by muse, mutect2, varscan2
- ZNF484 | c.683G>A p.C228Y | Missense Mutation (SNP) | VAF 26/269 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs150458752; called by muse, mutect2
- ZNF507 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.054); catalogued as rs766773762; called by muse, mutect2, varscan2
- ZNF808 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs778722618; called by muse, mutect2, varscan2
- ABCA1 | c.3229A>C p.K1077Q | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); called by muse, mutect2
- ABCA13 | c.2552A>G p.E851G | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- ADAM30 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ADAM33 | c.1211G>A p.C404Y | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1772G>A p.C591Y | Missense Mutation (SNP) | VAF 108/524 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY8 | c.2106C>A p.H702Q | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.039); called by muse, mutect2
- ADGRF2 | c.1195T>A p.S399T (on ENST00000296862 / NM_001368115.2; = p.S331T on NM_153839.7) | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.912); called by muse, mutect2
- ALOX5 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2
- ANKRD61 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, varscan2
- APOB | c.9769_9774del p.N3257_V3258del | In Frame Del (DEL) | VAF 60/281 reads (21%) | called by mutect2, pindel, varscan2
- ARHGAP33 | c.2534G>C p.G845A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARRDC2 | c.479C>G p.P160R | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASRGL1 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1A1 | c.2488G>C p.D830H | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ATRX | c.7250A>T p.Q2417L | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- BIRC5 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- BIRC6 | c.9577C>T p.R3193C | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3634G>C p.E1212Q | Missense Mutation (SNP) | VAF 154/356 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); called by mutect2, varscan2
- BTBD19 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 28/263 reads (11%) | called by muse, mutect2
- C1QTNF8 | c.525C>A p.Y175* | Nonsense Mutation (SNP) | VAF 27/210 reads (13%) | called by mutect2, varscan2
- C1orf43 | c.285A>T p.Q95H (on ENST00000368521 / NM_001297718.2; = p.Q61H on NM_015449.4) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- C20orf194 | c.2873+1G>C p.X958_splice | Splice Site (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- C8orf88 | c.253T>A p.L85M | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CARS1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC168 | c.14041C>G p.Q4681E | Missense Mutation (SNP) | VAF 110/220 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- CDC42EP4 | c.613T>A p.S205T | Missense Mutation (SNP) | VAF 125/404 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CEP295 | c.4555A>T p.I1519F | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2
- CHGB | c.1292T>C p.M431T | Missense Mutation (SNP) | VAF 152/480 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL20A1 | c.2794G>A p.V932I | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- CTSG | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2
- DCUN1D5 | c.478G>C p.D160H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- DPYSL5 | c.695T>A p.V232D | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DUS3L | c.1438C>G p.Q480E | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- F5 | c.1940G>C p.R647P | Missense Mutation (SNP) | VAF 76/664 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- FAM83G | c.-19_3del | Translation Start Site (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- FBXL19 | c.1919T>A p.L640Q | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FBXW9 | c.1377_1387del p.N460Gfs*? (on ENST00000587955; = p.N440Gfs*62 on NM_032301.3) | Frame Shift Del (DEL) | VAF 70/307 reads (23%) | called by mutect2, pindel, varscan2
- FGF21 | c.143A>T p.Y48F | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.328); called by mutect2, varscan2
- FRMD6 | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 28/143 reads (20%) | called by muse, mutect2, varscan2
- GLYATL3 | c.253T>C p.Y85H | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPR135 | c.1057C>G p.L353V | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.012); called by muse, varscan2
- HEATR1 | c.4507G>C p.E1503Q | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.243); called by muse, mutect2
- HMGN1 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HMMR | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- HNRNPM | c.2097C>G p.F699L | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HOXD10 | c.255C>A p.N85K | Missense Mutation (SNP) | VAF 23/240 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-35 | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 12/125 reads (10%) | called by muse, mutect2, varscan2
- INTS7 | c.254_259del p.K85_V86del | In Frame Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- ITGA9 | c.115C>G p.H39D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KIAA1671 | c.28A>C p.I10L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KIF4A | c.2932G>C p.E978Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- LINGO1-AS1 | n.195G>A | Splice Region (SNP) | VAF 15/78 reads (19%) | called by mutect2, varscan2
- LLGL2 | c.1392C>G p.S464R | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- LMX1A | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPKAPK2 | c.746T>C p.L249P | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAVS | c.1159-1G>C p.X387_splice | Splice Site (SNP) | VAF 13/182 reads (7%) | called by muse, mutect2
- MGAT5B | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- MLYCD | c.173A>G p.E58G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MYO19 | c.1231+5C>T | Splice Region (SNP) | VAF 45/129 reads (35%) | called by muse, mutect2, varscan2
- MYO7B | c.4669G>T p.V1557L | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NEXMIF | c.3863A>G p.E1288G | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NIBAN1 | c.533del p.F178Sfs*14 | Frame Shift Del (DEL) | VAF 19/143 reads (13%) | called by mutect2, pindel, varscan2
- NOD1 | c.73A>C p.S25R | Missense Mutation (SNP) | VAF 65/458 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.141); called by mutect2, varscan2
- NRAS | c.542G>C p.C181S | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- NUCB2 | c.393C>A p.D131E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- OBI1 | c.1694A>T p.D565V | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- OR10H1 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 46/477 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR5AS1 | c.151_156del p.I51_N52del | In Frame Del (DEL) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- OR5L1 | c.416A>T p.K139M | Missense Mutation (SNP) | VAF 277/465 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OXER1 | c.1028T>C p.F343S | Missense Mutation (SNP) | VAF 16/377 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- PARG | c.1620G>T p.Q540H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- PEX16 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 79/444 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLD2 | c.861-5_893del p.X287_splice | Splice Site (DEL) | VAF 11/84 reads (13%) | called by mutect2, pindel
- PNP | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 184/593 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- POTED | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 19/484 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- PRX | c.1093T>A p.F365I | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- PSMB7 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- PSMD3 | c.206C>G p.T69R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by mutect2, varscan2
- PTPN4 | c.1356-24_1358del p.X452_splice | Splice Site (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- RCE1 | c.38C>A p.S13* | Nonsense Mutation (SNP) | VAF 14/34 reads (41%) | called by muse, varscan2
- ROR2 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 113/312 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RTEL1 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 27/261 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2
- S1PR3 | c.70T>A p.Y24N | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SAMD7 | c.461G>C p.R154T | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SCAF11 | c.3621G>A p.M1207I | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SHE | c.1054T>C p.F352L | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC15A3 | c.1559C>G p.P520R | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.809); called by muse, mutect2
- SLC35F1 | c.911T>A p.I304K | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- SLC9A8 | c.1357A>G p.I453V | Missense Mutation (SNP) | VAF 498/701 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SPAG8 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TARS3 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 80/139 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TG | c.7285_7315del p.A2429Rfs*34 | Frame Shift Del (DEL) | VAF 174/1153 reads (15%) | called by mutect2, pindel, varscan2
- TM4SF19 | c.131C>A p.T44N | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- TMEM269 | c.662T>G p.L221R (on ENST00000536543; = p.L179R on NM_001354602.1) | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TONSL | c.2769G>C p.Q923H | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM8 | c.2862G>A p.W954* | Nonsense Mutation (SNP) | VAF 41/255 reads (16%) | called by muse, mutect2, varscan2
- TSC22D1 | c.3010G>C p.E1004Q (on ENST00000458659 / NM_183422.4; = p.E75Q on NM_006022.4) | Missense Mutation (SNP) | VAF 39/253 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSC22D4 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XDH | c.3500G>A p.C1167Y | Missense Mutation (SNP) | VAF 67/450 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF473 | c.612A>C p.E204D | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ZNFX1 | c.5600G>C p.G1867A | Missense Mutation (SNP) | VAF 22/596 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABCA13 | c.12318C>T p.D4106= | Silent (SNP) | VAF 28/94 reads (30%) | called by mutect2, varscan2
- ABCG8 | c.579G>A p.A193= | Silent (SNP) | VAF 50/318 reads (16%) | catalogued as rs747555833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM15 | c.2568G>A p.P856= (on ENST00000356955 / NM_207197.3; = p.P807= on NM_003815.5) | Silent (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2
- ASB10 | c.735T>C p.N245= (on ENST00000420175 / NM_001142459.2; = p.N230= on NM_080871.4) | Silent (SNP) | VAF 74/708 reads (10%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.594C>A p.L198= | Silent (SNP) | VAF 111/282 reads (39%) | called by mutect2, varscan2
- COL6A3 | c.4191G>A p.L1397= | Silent (SNP) | VAF 49/138 reads (36%) | called by muse, mutect2, varscan2
- COLEC12 | c.330C>A p.T110= | Silent (SNP) | VAF 38/235 reads (16%) | called by muse, mutect2, varscan2
- DAAM2 | c.1641G>T p.L547= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs1221253107; called by muse, varscan2
- DYNC2I1 | c.717A>G p.K239= | Silent (SNP) | VAF 33/164 reads (20%) | called by muse, mutect2, varscan2
- DZIP3 | c.1404C>T p.C468= | Silent (SNP) | VAF 38/593 reads (6%) | catalogued as rs1231254020; called by muse, mutect2
- EIF2B2 | c.183C>A p.I61= | Silent (SNP) | VAF 63/287 reads (22%) | called by mutect2, varscan2
- FIGN | c.1770T>G p.L590= | Silent (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- FLII | c.1092G>A p.E364= | Silent (SNP) | VAF 34/128 reads (27%) | called by mutect2, varscan2
- GALM | c.987G>A p.E329= | Silent (SNP) | VAF 28/201 reads (14%) | catalogued as rs1331830662; called by muse, mutect2, varscan2
- GJB2 | c.351C>T p.D117= | Silent (SNP) | VAF 114/402 reads (28%) | called by muse, mutect2, varscan2
- LMF1 | c.1212C>T p.N404= | Silent (SNP) | VAF 41/196 reads (21%) | catalogued as rs1450230693; called by muse, mutect2, varscan2
- LRFN1 | c.1110T>C p.C370= | Silent (SNP) | VAF 48/619 reads (8%) | called by muse, mutect2
- MAP3K19 | c.814T>C p.L272= | Silent (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- ME1 | c.1302T>C p.S434= | Silent (SNP) | VAF 18/118 reads (15%) | called by muse, varscan2
- MROH8 | c.1035G>A p.K345= | Silent (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2
- NLRP11 | c.2517G>C p.L839= | Silent (SNP) | VAF 12/109 reads (11%) | called by mutect2, varscan2
- NSUN5 | c.1275C>T p.V425= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as rs782690161, COSV99392314; called by muse, mutect2, varscan2
- OR51D1 | c.105C>A p.T35= | Silent (SNP) | VAF 61/273 reads (22%) | called by muse, mutect2, varscan2
- OTOGL | c.2985C>T p.N995= (on ENST00000547103; = p.N986= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs374656183; called by muse, mutect2, varscan2
- OXA1L | c.150A>G p.A50= | Silent (SNP) | VAF 43/281 reads (15%) | called by muse, mutect2, varscan2
- PDE1B | c.1281C>T p.F427= | Silent (SNP) | VAF 41/167 reads (25%) | catalogued as COSV54491315; called by muse, mutect2, varscan2
- PGGHG | c.1375C>T p.L459= | Silent (SNP) | VAF 9/246 reads (4%) | called by muse, mutect2
- PID1 | c.534C>T p.N178= (on ENST00000354069 / NM_001330156.1; = p.N176= on NM_017933.5) | Silent (SNP) | VAF 81/495 reads (16%) | catalogued as rs146933858; called by muse, mutect2, varscan2
- PSMB9 | c.216C>A p.A72= | Silent (SNP) | VAF 24/147 reads (16%) | called by muse, mutect2, varscan2
- PTGER4 | c.1164C>T p.I388= | Silent (SNP) | VAF 115/879 reads (13%) | called by muse, mutect2, varscan2
- PTPRT | c.2520G>A p.Q840= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV62019032; called by muse, mutect2
- RAB4B | c.45C>T p.G15= | Silent (SNP) | VAF 78/176 reads (44%) | catalogued as rs1474780429; called by muse, mutect2, varscan2
- RRBP1 | c.2655C>T p.D885= (on ENST00000377813 / NM_001365613.2; = p.D452= on NM_004587.3) | Silent (SNP) | VAF 41/268 reads (15%) | catalogued as rs373604252; called by muse, mutect2, varscan2
- TDRD6 | c.1194A>G p.T398= | Silent (SNP) | VAF 70/741 reads (9%) | called by muse, mutect2
- TMC5 | c.918A>T p.S306= | Silent (SNP) | VAF 59/134 reads (44%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.1068C>T p.P356= | Silent (SNP) | VAF 36/234 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.82584A>G p.Q27528= (on ENST00000591111; = p.Q20104= on NM_003319.4) | Silent (SNP) | VAF 42/286 reads (15%) | called by muse, mutect2, varscan2
- USP11 | c.1818C>T p.S606= (on ENST00000218348; = p.S563= on NM_001371072.1) | Silent (SNP) | VAF 168/224 reads (75%) | called by muse, mutect2, varscan2
- ZBTB16 | c.1845G>C p.S615= | Silent (SNP) | VAF 50/475 reads (11%) | called by muse, mutect2, varscan2
- ZNRF4 | c.864G>A p.P288= | Silent (SNP) | VAF 44/274 reads (16%) | catalogued as rs367609822; called by muse, mutect2, varscan2
- AATK | c.190-704G>A | Intron (SNP) | VAF 25/186 reads (13%) | catalogued as rs375500605; called by muse, mutect2, varscan2
- ABHD4 | chr14:22598236 C>A | 5'Flank (SNP) | VAF 22/126 reads (17%) | catalogued as rs1278074915; called by muse, varscan2
- BCAS1 | c.927+2415C>G | Intron (SNP) | VAF 42/350 reads (12%) | called by muse, mutect2, varscan2
- CDH19 | c.1336+2274G>T | Intron (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- DDX39B | c.-145C>A | 5'UTR (SNP) | VAF 23/74 reads (31%) | called by mutect2, varscan2
- IQCK | c.-30_-6del | 5'UTR (DEL) | VAF 67/157 reads (43%) | called by mutect2, pindel, varscan2
- KCTD1 | c.-15-45878A>C | Intron (SNP) | VAF 31/130 reads (24%) | called by mutect2, varscan2
- KLK13 | c.52+1230_52+1231insT | Intron (INS) | VAF 128/391 reads (33%) | called by mutect2, pindel, varscan2
- LINC00293 | n.426-26T>C | Intron (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2, varscan2
- LINC00905 | n.1065G>C | RNA (SNP) | VAF 41/310 reads (13%) | called by muse, mutect2, varscan2
- LLCFC1 | c.157+89A>T | Intron (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- MGAM | c.4619-2655A>G | Intron (SNP) | VAF 22/189 reads (12%) | catalogued as rs767644933; called by muse, mutect2, varscan2
- MKS1 | c.1274-33G>T | Intron (SNP) | VAF 43/299 reads (14%) | called by muse, mutect2, varscan2
- MOK | c.122+4814T>C | Intron (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- NCSTN | c.86-144G>C | Intron (SNP) | VAF 47/471 reads (10%) | called by muse, mutect2, varscan2
- NDE1 | c.1030+2942G>A | Intron (SNP) | VAF 30/73 reads (41%) | catalogued as rs766128896; called by muse, mutect2, varscan2
- POLR2H | c.-34T>A | 5'UTR (SNP) | VAF 54/554 reads (10%) | called by muse, mutect2
- SNX20 | chr16:50669112 C>A | 3'Flank (SNP) | VAF 21/134 reads (16%) | called by mutect2, varscan2
- TKTL1 | c.135-298_135-296del | Intron (DEL) | VAF 10/86 reads (12%) | called by mutect2, varscan2
- TM4SF1 | c.*89del | 3'UTR (DEL) | VAF 13/82 reads (16%) | called by mutect2, pindel, varscan2
- TNFSF10 | c.133-3433G>C | Intron (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- TSHR | c.318-24C>G | Intron (SNP) | VAF 45/223 reads (20%) | called by muse, mutect2, varscan2
- UCHL5 | c.945+679C>A | Intron (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100815326; called by muse, mutect2, varscan2
- WDR1 | c.17-122G>C | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.784+253C>G | Intron (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- ZNF252P | n.840C>A | RNA (SNP) | VAF 44/371 reads (12%) | called by muse, mutect2, varscan2
